Somatic mutation profile of tumor specimen TCGA-AA-3544-01A (aliquot TCGA-AA-3544-01A-01D-1953-10) from TCGA case TCGA-AA-3544, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 68.3 years (24,959 days).
Specimen TCGA-AA-3544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89c80f92-bef0-4c82-a17d-a8dc65126627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3544-10A (Blood Derived Normal), aliquot TCGA-AA-3544-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c83277e-24bb-4a61-83b8-ee1204790600

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 15, Silent 10, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF40 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs1348179184, COSV100070219; called by muse, mutect2, varscan2
- CASKIN1 | c.3470G>A p.R1157Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV100399353, COSV100399883; called by muse, mutect2
- DHX34 | c.2464C>G p.R822G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1016171531, COSV100169424; called by muse, mutect2, varscan2
- DSCAM | c.4981G>A p.D1661N | Missense Mutation (SNP) | VAF 204/561 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs748635134, COSV68021632; called by muse, mutect2, varscan2
- EEF2 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100500568, COSV58578496; called by muse, mutect2, varscan2
- METTL6 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101085017; called by muse, mutect2, varscan2
- OTUD7B | c.701G>T p.W234L | Missense Mutation (SNP) | VAF 121/418 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100967456; called by muse, mutect2, varscan2
- RGS22 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 115/756 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774013023, COSV62664363; called by muse, mutect2, varscan2
- S1PR5 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1394898768, COSV61013494; called by muse, mutect2, varscan2
- SP6 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100646982; called by muse, mutect2, varscan2
- SPEF2 | c.2713T>G p.S905A | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs781719061, COSV100606916; called by muse, mutect2, varscan2
- TLE4 | c.1145T>A p.M382K | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV99511729; called by muse, mutect2, varscan2
- TSPOAP1 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs761891028, COSV99270667; called by muse, mutect2, varscan2
- UBN2 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs752508519, COSV99943818; called by muse, mutect2, varscan2
- ZXDA | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 288/437 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774361347, COSV100699395; called by muse, mutect2, varscan2
- CCDC18 | c.1451dup p.S484Rfs*2 | Frame Shift Ins (INS) | VAF 32/127 reads (25%) | called by mutect2, pindel, varscan2
- MICAL1 | c.3133_3134del p.D1045Cfs*? | Frame Shift Del (DEL) | VAF 36/65 reads (55%) | called by pindel, varscan2
- ANKRD2 | c.282C>T p.R94= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs199935455, COSV100080793; called by muse, mutect2, varscan2
- CNGA1 | c.1164C>T p.I388= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs550831196, COSV62052849; called by muse, mutect2, varscan2
- COG1 | c.69G>A p.E23= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100245244; called by muse, mutect2, varscan2
- GPX3 | c.597C>T p.H199= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV100161252; called by muse, mutect2, varscan2
- IRF2BP1 | c.690G>A p.R230= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs991179115, COSV100138847; called by muse, mutect2, varscan2
- MARK1 | c.2022C>T p.T674= | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as rs749814836, COSV100857149; called by muse, mutect2, varscan2
- MPND | c.1317C>T p.L439= | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as rs549891396, COSV53660563; called by muse, mutect2, varscan2
- NKX2-1 | c.480G>A p.P160= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1208826555, COSV61387560; called by muse, mutect2, varscan2
- RELCH | c.165G>C p.L55= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99901747; called by muse, mutect2, varscan2
- SIX6 | c.726C>T p.S242= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs770148963, COSV59802995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
